Surgical pathology report (de-identified scan), TCGA case TCGA-D1-A17C, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Mayo Clinic, specimen TCGA-D1-A17C-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology

SLIDE DISPOSITION:

DIAGNOSIS:

A. Uterus, bilateral ovaries and fallopian tubes; hysterectomy and bilateral salpingo-oophorectomy: FIGO grade I (of III) endometrial adenocarcinoma, endometrioid type, is identified forming a mass (2.9 x 2.5 x 1.1 cm) located in the posterior and left lateral wall of the endometrial cavity. The tumor superficially invades 0.3 cm into the myometrium (total myometrial thickness, 2.2 cm). The lower uterine segment is uninvolved by tumor. Lymphovascular space invasion is not identified. The margins are negative for tumor. The cervix is unremarkable. There are multiple (2) intramural leiomyomas (0.5 cm and 0.6 cm in greatest dimension) and a single subserosal leiomyoma (0.5 cm in greatest dimension) in the myometrium. The bilateral ovaries and remnants of fallopian tubes are unremarkable.

With available surgical material, [AJCC (7th edition) pT1bNX].

This final pathology report is based on the gross/macroscopic examination and the frozen section histologic evaluation of the specimen(s). Hematoxylin and Eosin (H&E) permanent sections are reviewed to confirm these findings. Any substantive changes identified on permanent section review will be reflected in a revised report.

[page 2 of 2]
GROSS DESCRIPTION:

A. Received fresh labeled "uterus and bilateral tubes/ovaries" is a 110.0 gram uterus with attached bilateral fallopian tube remnants, ovaries and an unremarkable cervix. The uterine serosa is smooth. There is a 2.9 x 2.5 x 1.1 cm polypoid mass in the posterior and left lateral wall of the endometrial cavity which grossly appears to invade 0.3 cm into the 2.2 cm thick myometrium. There are multiple (2) intramural leiomyomata (0.5 cm and 0.6 cm in greatest dimension) and a single subserosal leiomyoma (0.5 cm in greatest dimension). There is a 2.3 x 1.0 x 0.9 cm right ovary with a smooth outer surface and a solid cut surface with a 0.9 x 0.3 cm right fallopian tube remnant. There is a 2.1 x 1.0 x 1.0 cm left ovary with a smooth outer surface and a solid cut surface with a 0.7 x 0.3 cm left fallopian tube remnant. Representative sections submitted.

BLOCK SUMMARY:

Part A: Uterus, bilateral tubes / ovaries

- 1 Endometrium post wall-1
- 2 Endometrium post wall-2
- 3 Endometrium post wall-3
- 4 Lower uterine segment
- 5 Cervix
- 6 Right ovary
- 7 Right fallopian tube
- 8 Left ovary
- 9 Left fallopian tube

Source: NCI Genomic Data Commons file 8fdc5215-91f2-484c-a52c-907bddc72da8 (TCGA-D1-A17C.213A073E-C5E1-4BA8-B4D5-23C92E539FA5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).